Somatic mutation profile of tumor specimen MBCProject_0734_T1A_WES (aliquot MBCProject_0734_T1A_WES_1) from CMI case MBCProject_0734, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct and lobular carcinoma; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 56.1 years (20,505 days).
Specimen MBCProject_0734_T1A_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d5d67399-31fd-4af7-8985-7100c2a13fcd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0734_SALIVA (Saliva), aliquot MBCProject_0734_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be5af0f8-dfe3-4b98-ab59-c86644a904ab

The open-access MAF lists 2 somatic variants for this specimen: 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NKX6-1 | c.513G>A p.P171= | Silent (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2
- ARMCX4 | c.1039-4043G>A | Intron (SNP) | VAF 16/66 reads (24%) | catalogued as rs782152145, COSV61449103; called by muse, varscan2
